CCDI case PBBVYY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/08d04246-6b73-4af3-a638-85975d2d6f93

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,386 days).

Biospecimens (3 samples)
- Sample 0DMKKE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKKP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMKL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
